Somatic mutation profile of tumor specimen TCGA-P3-A6T8-01A (aliquot TCGA-P3-A6T8-01A-11D-A34J-08) from TCGA case TCGA-P3-A6T8, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 54.1 years (19,754 days).
Specimen TCGA-P3-A6T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9875f180-cea8-47fe-a759-a189acfa5ed6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T8-10A (Blood Derived Normal), aliquot TCGA-P3-A6T8-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d49459b9-ab1e-4520-b1fe-5bf6c2dc36c7

The open-access MAF lists 93 somatic variants for this specimen: 75 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 16, Frame Shift Del 5, Nonsense Mutation 3, Frame Shift Ins 3, 3'UTR 1, Nonstop Mutation 1, In Frame Del 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100448190; called by muse, mutect2, varscan2
- ACTRT1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100947528; called by muse, mutect2, varscan2
- ADARB2 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101186783, COSV67234649; called by muse, mutect2, varscan2
- ADCK5 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.713); catalogued as rs1554860430, COSV100450299; called by muse, mutect2, varscan2
- AHNAK | c.13157C>T p.S4386F | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99946439; called by muse, mutect2, varscan2
- AKAP7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs186732768, COSV99541374; called by muse, mutect2, varscan2
- AXDND1 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100858290; called by muse, mutect2, varscan2
- C2CD5 | c.2627A>G p.K876R | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV100448587; called by muse, mutect2, varscan2
- CCDC141 | c.1896T>A p.N632K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV99836480; called by muse, mutect2, varscan2
- CCDC185 | c.696C>G p.S232R | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as COSV100838772; called by muse, mutect2
- CD163 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100775750; called by muse, mutect2, varscan2
- COL22A1 | c.3970G>A p.G1324S | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277273; called by muse, mutect2, varscan2
- CR1L | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.593); catalogued as COSV54327338, COSV99687002; called by muse, mutect2, varscan2
- CRYBG1 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100954426; called by muse, mutect2, varscan2
- CYP39A1 | c.687C>A p.N229K | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.049); catalogued as COSV99242029; called by muse, mutect2, varscan2
- DNAH7 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.177); catalogued as rs200552499, COSV56750336; called by muse, mutect2, varscan2
- DSEL | c.1373T>A p.I458K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100025433; called by muse, mutect2, varscan2
- EIF2S2 | c.398T>C p.F133S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV100894946; called by muse, mutect2, varscan2
- FAM13A | c.1415G>T p.S472I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99983168; called by muse, mutect2, varscan2
- FANCA | c.279T>A p.F93L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV101224676; called by muse, mutect2, varscan2
- FEZF1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100484450, COSV58658874; called by muse, mutect2, varscan2
- GYPE | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); catalogued as COSV100679212; called by muse, mutect2
- H2BW1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556337689, COSV54220625; called by muse, mutect2, varscan2
- IGSF11 | c.872C>T p.P291L (on ENST00000393775 / NM_001015887.3; = p.P290L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763321160, COSV100677168; called by muse, mutect2, varscan2
- KIZ | c.1076A>T p.K359M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as COSV99851966; called by muse, mutect2, varscan2
- KMT2E | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs150358701; called by muse, mutect2, varscan2
- LAX1 | c.271A>C p.N91H | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920015; called by muse, mutect2, varscan2
- LHCGR | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs770957396, COSV99683415; called by muse, mutect2, varscan2
- LMO7 | c.1937C>G p.P646R (on ENST00000357063; = p.P376R on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV100412759, COSV58535620; called by muse, mutect2, varscan2
- LRP1B | c.3817A>G p.I1273V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.952); catalogued as COSV101254550; called by muse, mutect2, varscan2
- LRRCC1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV100835367; called by muse, mutect2, varscan2
- MAP7D1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV100294325, COSV60218038; called by muse, mutect2, varscan2
- MCF2 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644627; called by muse, mutect2, varscan2
- METTL14 | c.1099A>G p.S367G | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV101183381; called by muse, mutect2, varscan2
- NAV3 | c.2858G>A p.S953N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99888647; called by muse, mutect2, varscan2
- NLRP8 | c.740A>G p.E247G | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99404964; called by muse, mutect2, varscan2
- NSD1 | c.7992del p.G2666Efs*95 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as COSV61778027; called by mutect2, pindel, varscan2
- NUP188 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs373808238; called by muse, mutect2, varscan2
- OR4D9 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100259757; called by muse, mutect2, varscan2
- OSBP | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99802827; called by muse, mutect2, varscan2
- PCNT | c.6206A>C p.Q2069P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100855236; called by muse, mutect2, varscan2
- PDE10A | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100604851, COSV63050501; called by muse, mutect2, varscan2
- PDE11A | c.1566C>A p.H522Q | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.903); catalogued as COSV99611353; called by muse, mutect2, varscan2
- PIWIL1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.205); catalogued as COSV99806176; called by muse, mutect2, varscan2
- RBM45 | c.1047G>A p.W349* (on ENST00000616198 / NM_001365579.1; = p.W347* on NM_152945.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | catalogued as COSV99617587; called by muse, mutect2, varscan2
- RLIM | c.1705A>C p.T569P | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100222895; called by muse, mutect2, varscan2
- ROBO3 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs1294649886, COSV101184975; called by muse, mutect2
- RSPH9 | c.829T>C p.*277Qext*9 | Nonstop Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as rs141935442; called by muse, mutect2, varscan2
- SLC12A7 | c.2962G>A p.A988T | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs374026955, COSV53754023; called by muse, mutect2, varscan2
- SLCO1C1 | c.926A>T p.N309I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99858787; called by muse, mutect2, varscan2
- SMOC1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV100734458; called by muse, mutect2, varscan2
- SNTB1 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV67326217; called by muse, mutect2, varscan2
- TCTE1 | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV101025365; called by muse, mutect2, varscan2
- TLR2 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs370330063; called by muse, mutect2, varscan2
- TNXB | c.4840C>T p.P1614S (on ENST00000647633; = p.P1367S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.871); catalogued as COSV100926089; called by muse, mutect2, varscan2
- TRRAP | c.9091A>G p.M3031V (on ENST00000359863 / NM_001244580.1; = p.M3002V on NM_003496.3) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.247); catalogued as COSV100722242; called by muse, mutect2, varscan2
- VWA5A | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.434); catalogued as COSV100827793; called by muse, mutect2, varscan2
- WDR17 | c.986T>C p.F329S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV54578251, COSV99707203; called by mutect2, varscan2
- WDR70 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs970163407, COSV99458142; called by muse, mutect2, varscan2
- ZAN | c.4984C>T p.H1662Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100769450; called by muse, mutect2
- ZBBX | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs908045796, COSV100283571; called by muse, mutect2, varscan2
- ZBTB41 | c.2605A>G p.I869V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV100962970; called by muse, mutect2, varscan2
- ZNF254 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs1334919781, COSV100741556; called by muse, mutect2, varscan2
- ZNF536 | c.2890T>A p.S964T | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV100834932; called by muse, mutect2, varscan2
- ZNF599 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs946911835, COSV100251056; called by muse, mutect2, varscan2
- ZNF836 | c.1319A>T p.K440I | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100440755, COSV59082495; called by muse, mutect2, varscan2
- BAZ1A | c.4469dup p.L1490Ffs*4 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- CASP5 | c.520_522del p.L174del | In Frame Del (DEL) | VAF 31/106 reads (29%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.1939_1945del p.S647Pfs*123 | Frame Shift Del (DEL) | VAF 41/80 reads (51%) | called by mutect2, pindel, varscan2
- NRDE2 | c.1016dup p.M339Ifs*37 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- PLEKHA8 | c.614dup p.P206Tfs*4 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- SMAD9 | c.1154del p.F385Sfs*24 (on ENST00000379826 / NM_001127217.3; = p.F348Sfs*24 on NM_005905.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- SPOCK2 | c.832_842del p.Y278Hfs*9 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | called by mutect2, pindel, varscan2
- AGPS | c.670C>T p.L224= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99931170; called by muse, varscan2
- CELA2B | c.561C>A p.S187= | Silent (SNP) | VAF 114/257 reads (44%) | catalogued as COSV101025732; called by muse, mutect2, varscan2
- COLGALT1 | c.453G>T p.L151= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99394913; called by muse, mutect2, varscan2
- CSE1L | c.414T>C p.F138= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99521920; called by muse, mutect2, varscan2
- DPY19L2 | c.2190C>G p.P730= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100193051, COSV61043064; called by muse, mutect2, varscan2
- FBXO34 | c.213C>T p.C71= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100571884; called by muse, mutect2, varscan2
- FLG | c.10161C>G p.L3387= | Silent (SNP) | VAF 82/431 reads (19%) | catalogued as COSV100911313, COSV100911608; called by muse, mutect2, varscan2
- IFT52 | c.966C>A p.L322= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100887563; called by muse, mutect2, varscan2
- ODF1 | c.87C>T p.D29= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs369351331; called by muse, mutect2, varscan2
- OR10Q1 | c.510G>T p.L170= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100372204; called by muse, mutect2, varscan2
- OR2T33 | c.181C>T p.L61= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV100531737; called by muse, mutect2, varscan2
- PCDHGB4 | c.1431G>A p.P477= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as rs1257183989, COSV54055943; called by muse, mutect2, varscan2
- ROBO3 | c.2808C>T p.S936= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV101184976; called by muse, mutect2
- TUBA1A | c.969G>T p.V323= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV99853670; called by muse, mutect2, varscan2
- WDR70 | c.369C>T p.P123= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV99458141; called by muse, mutect2, varscan2
- ZNF37A | c.1428C>T p.F476= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100697317; called by muse, mutect2, varscan2
- MAP3K6 | c.*55G>C | 3'UTR (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100539229; called by muse, mutect2, varscan2
- MYBPC1 | chr12:101684407 T>C | 3'Flank (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100637848; called by muse, mutect2, varscan2
